Surgical pathology report (de-identified scan), TCGA case TCGA-P3-A6T5, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site  Fred Hutchinson, specimen TCGA-P3-A6T5-01A (Primary Tumor).

[page 1 of 2]
ICD-3

Carcinoma, squamous cell NOS
8676/3

Date ^{SCC} Lower alveolar ridge mucosa
path CO3.1
Mandibular gingiva CO3.1
8/9/13

CASE: RECEIVED:

CLINICAL DATA: SCC of left mandibular mucosa.

GROSS DESCRIPTION:

A) Received fresh designated "..., left composite resection" is a 4 AP x 2.5 ML x 2 SI cm portion of tissue that has been oriented by the surgeon with a single stitch designated anterior and a double stitch designated lingual. The lateral aspect of the specimen has bone. The specimen is covered by tan, glistening mucosa with a central 2.5 x 1.5 cm ulcerated, ragged area. The center of the lesion has been inked and tissue has been removed for research studies. The lesion appears to be located approximately 0.5 cm from the anterior margin and >0.5 cm from the posterior margin. The specimen is inked as follows: Anterior - red; posterior - orange; mucosal and bony lateral margin - green; bony and soft tissue deep margins - black; lingual/medial - blue. The specimen is serially sectioned and the mass does not appear to involve the red inked margin and it is located 0.3 cm from the orange margin. The tumor appears to abut the blue inked and black inked margins and appears to extend close to the bony green margin. Bone sections are decalcified. 80% of the specimen is submitted as follows: A1 - mass, blue and black inked margins; A2 - mass, orange, blue, and black inked margins; A3 - orange, blue, and black inked margins and red inked margin; A4 - blue inked margins; A5 - orange inked margin; A6 - blue inked margin; remaining sections submitted following decalcification: A6- margins, green and orange; A7- orange inked margin; A8-A9 green inked margin; A10- red inked margin.

B) Received fresh in a container for frozen labeled "..., anterior" is a 0.5 cm tan, irregular soft tissue which is marked with black ink and entirely submitted for frozen. The frozen section residue is submitted in block

C) Received fresh in a container for frozen labeled "..., lateral" is a 0.5 cm tan, irregular soft tissue. The specimen is marked with blue ink and entirely submitted for frozen. The frozen section residue is submitted in block

D) Received fresh in a container for frozen labeled "..., posterior" is a 0.5 cm tan, irregular soft tissue. The specimen is entirely submitted for frozen. The frozen section residue is submitted in block

E) Received fresh in a container for frozen labeled "..., medial" is a 0.5 cm tan, irregular soft tissue which is submitted in toto in cassette

F) Received fresh in a container for frozen labeled "..., deep" is a 0.5 cm tan, irregular soft tissue which is marked with blue ink and entirely submitted for frozen. The frozen section residue is submitted in block

G) Received in formalin labeled "..., left neck contents" is an 11.5 x 4.0 x 1.5 cm yellow, lobulated, focally glandular portion of fibrofatty tissue. There is a single suture attached to the level I region, and a double suture attached to the level III region. The level I region is sectioned, and there is a 3.5 x 3.0 x 1.5 cm tan, lobulated salivary gland. It has tan, lobulated cut surfaces, and no masses or lesions are identified. The adipose tissue

[page 2 of 2]
attached to the salivary gland is sectioned and has fatty cut surfaces containing a few lymph node candidates ranging from 0.2 to 1.0 cm. The remaining adipose tissue in levels II and III are sectioned and have fatty cut surfaces, and additional lymph nodes are identified ranging from 0.2 to 1.0 cm. Representative sections are submitted as follows: G1 - random salivary gland; G2 - three individual lymph node candidates level I; G3 - one bisected lymph node level I; G4 - three individual lymph node candidates level II; G5 - three individual lymph node candidates level II; G6 - six individual lymph node candidates level III; G7 - seven individual lymph node candidates level III; G8 - six individual lymph node candidates level III.

H) Received in formalin labeled "... level I lymph node" is a 1.5 x 1.0 x 0.3 cm tan-yellow, focally hemorrhagic portion of adipose tissue. The specimen is entirely submitted in cassette H1.

INTRAOPERATIVE CONSULTATION:

BFS-FFS) All margins negative for neoplasia

FINAL DIAGNOSIS:

A) Left composite resection: Invasive squamous cell carcinoma, moderately differentiated, with the following features:

1. 2.5 cm in greatest dimension.
2. Carcinoma abuts (<0.1 cm) deep margin and it is located 0.1 cm from lingual/medial submucosal margin, 0.2 cm from posterior submucosal margin, 0.3 cm from lateral mucosal and submucosal margins, and 0.6 cm from anterior mucosal and submucosal margins; mucosal and bone margins are free of carcinoma (please see separately submitted margins).
3. Carcinoma focally invades mandibular bone and involves underlying salivary gland tissue.
4. Perineural invasion of small nerves is identified.
5. Minimum pathological stage pT4a N0 MX (AJCC 6th ed; 2002).

B-D) Separately submitted margins, anterior, lateral and posterior, biopsies: No carcinoma identified.

E, F) Separately submitted margins, medial and deep, biopsies: No carcinoma identified.

G) Left neck contents, dissection:

1. 29 lymph nodes with no carcinoma identified (0/29).
2. Salivary gland with fatty change; no carcinoma identified.

H) "Level I lymph node," dissection: Mature adipose tissue with no carcinoma identified; no lymphoid tissue identified.

Procedures used to establish the diagnosis:
Routine

Dual/Synchronous Pathology Noted		///

Source: NCI Genomic Data Commons file 4b79b638-3e18-48be-add9-20a5a351f148 (TCGA-P3-A6T5.A67DC0DE-0790-4DED-BC98-686DA4E5195C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).